TCGA case TCGA-31-1953 — Ovarian Serous Cystadenocarcinoma (TCGA-OV)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Cystic, Mucinous and Serous Neoplasms; Primary site: Ovary; Tissue source site: Imperial College. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/61feee94-3ac9-42fe-aaa3-dc6a3efe563c

Demographics
Sex at birth: female; Race: asian; Ethnicity: not hispanic or latino; Age at index: 52 years; Vital status: Alive.

Diagnoses (2)
1. Serous cystadenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8441/3; ICD-10 code: C56.9; Tissue or organ of origin: Ovary; Site of resection or biopsy: Ovary; Laterality: Bilateral; Classification of tumor: primary; Age at diagnosis: 52.2 years (19,064 days); Year of diagnosis: 2008; Method of diagnosis: Surgical Resection; FIGO stage: Stage IIIC; Tumor grade: G3; Prior treatment: No; Days to last follow up: 204 days.
   Pathology details: Lymphatic invasion present: No; Vascular invasion present: No.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin; Treatment intent type: Adjuvant; Days to treatment start: 23 days; Days to treatment end: 65 days; Number of cycles: 3; Treatment dose: 1,350 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Paclitaxel; Treatment intent type: Adjuvant; Days to treatment start: 23 days; Days to treatment end: 65 days; Number of cycles: 3; Treatment dose: 840 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin + Paclitaxel; Initial disease status: Progressive Disease; Days to treatment start: 100 days; Treatment outcome: Treatment Ongoing; Route of administration: Intravenous.
   Recorded as not given: adjuvant Radiation Therapy, NOS.
2. Recurrence of diagnosis 1 (Serous cystadenocarcinoma, NOS). Age at diagnosis: 52.4 years (19,134 days); Days to diagnosis: 70 days; Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Recurrent Disease.
   Recorded as not given: Radiation Therapy, NOS, for recurrent disease.

Follow-up (3 entries)
- Day 70 (post initial treatment): Progression or recurrence: Yes; Days to recurrence: 70 days; Evidence of recurrence type: Convincing Image Source.
- Days to follow up: 204 days; Disease response: With Tumor.
- ECOG performance status: 1; Timepoint: Prior to Adjuvant Therapy.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-31-1953-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 1; Intermediate dimension: 0.5; Shortest dimension: 0.1.
  Slide TCGA-31-1953-01A-01-TS1: Section location: Top; Percent tumor cells: 90; Percent tumor nuclei: 95; Percent normal cells: 0; Percent necrosis: 2; Percent stromal cells: 8; Percent lymphocyte infiltration: 1.
  Slide TCGA-31-1953-01A-01-BS1: Section location: Bottom; Percent tumor cells: 90; Percent tumor nuclei: 95; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 10; Percent lymphocyte infiltration: 3.
- Sample TCGA-31-1953-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Serous Cystadenocarcinoma; Tumor status: With tumor; History neoadjuvant treatment: No; Performance status timing: Pre-Adjuvant Therapy; Method initial path diagnosis: Tumor resection; Lymphovascular invasion indicator: No.
- Drug treatment 1: Pharmaceutical therapy drug name: Paciltaxel.
- Drug treatment 1, Route of administrations: Route of administration: IV.
- Drug treatment 2: Pharmaceutical therapy drug name: Paciltaxle; Therapy regimen: Progression.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 204 days; disease-specific survival: no event (censored), 204 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 70 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-31-1953-01A-01D-0648-01): tumor purity 0.64, ploidy 3.77, whole-genome doublings 1.
